Somatic mutation profile of tumor specimen C3N-01945-01 (aliquot CPT0163530006) from CPTAC case C3N-01945, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 61.3 years (22,403 days).
Specimen C3N-01945-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0202da7c-6ddc-4cdc-8239-66cc1d2cf7e5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01945-31 (Blood Derived Normal), aliquot CPT0163590002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ef82e33-7181-4276-8dc6-f9b3adf8e42a

The open-access MAF lists 147 somatic variants for this specimen: 91 protein-altering or splice-affecting, 39 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 39, Intron 8, Nonsense Mutation 5, 5'UTR 4, RNA 2, 3'UTR 2, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.737T>A p.M246K | Missense Mutation (SNP) | VAF 37/503 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587780074, CM157012, COSV52668375, COSV52693504, COSV52778210; ClinVar: likely pathogenic; called by muse, mutect2
- ACE | c.552G>A p.M184I | Missense Mutation (SNP) | VAF 123/936 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1172383595; called by muse, mutect2, varscan2
- ALG12 | c.1208C>T p.S403F | Missense Mutation (SNP) | VAF 51/910 reads (6%) | PolyPhen probably damaging (0.999); catalogued as COSV100427117; called by muse, mutect2
- ANKRD6 | c.1657G>A p.D553N (on ENST00000339746 / NM_001242809.2; = p.D548N on NM_014942.4) | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs201232548; called by muse, mutect2, varscan2
- BORA | c.1468G>C p.E490Q (on ENST00000613797; = p.E415Q on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/328 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.907); catalogued as COSV64695605, COSV64695902; called by muse, mutect2
- BRWD3 | c.763G>T p.A255S | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.808); catalogued as COSV100955816, COSV64748283; called by muse, mutect2
- C2orf81 | c.887G>C p.G296A | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.359); catalogued as COSV51762937; called by muse, mutect2
- CITED2 | c.173A>G p.Y58C | Missense Mutation (SNP) | VAF 149/856 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1449425945; called by muse, mutect2, varscan2
- COL22A1 | c.929G>C p.W310S | Missense Mutation (SNP) | VAF 21/415 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57335140; called by muse, mutect2
- CPA3 | c.325G>T p.D109Y | Missense Mutation (SNP) | VAF 24/296 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.061); catalogued as COSV99936478; called by muse, mutect2
- DVL2 | c.1936C>T p.P646S | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs1165698134; called by muse, mutect2
- FAT3 | c.2128G>A p.D710N | Missense Mutation (SNP) | VAF 27/297 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV53143248; called by muse, mutect2
- H3-3B | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 17/277 reads (6%) | catalogued as COSV54666696, COSV54666887; called by muse, mutect2
- KCTD20 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.163); catalogued as rs182729907; called by muse, mutect2
- KLC3 | c.74G>C p.R25P | Missense Mutation (SNP) | VAF 32/307 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as rs1305825219; called by muse, mutect2, varscan2
- KMT2D | c.16211C>T p.S5404F | Missense Mutation (SNP) | VAF 60/460 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56415409, COSV56435829; called by muse, mutect2, varscan2
- MAP2K1 | c.1046G>C p.R349T | Missense Mutation (SNP) | VAF 28/563 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1408378561, COSV57234324; called by muse, mutect2
- MYO3A | c.556G>A p.V186I | Missense Mutation (SNP) | VAF 44/629 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1331753934, COSV56319886; called by muse, mutect2
- NCR1 | c.505G>A p.G169R | Missense Mutation (SNP) | VAF 38/666 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as rs966441909, COSV52557489; called by muse, mutect2
- NFE2L3 | c.188C>T p.S63L | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1370852401; called by muse, mutect2
- NUDT10 | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.244); catalogued as COSV62854300; called by muse, mutect2, varscan2
- NUMA1 | c.3560C>T p.S1187L | Missense Mutation (SNP) | VAF 24/446 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as rs749408043, COSV61184030, COSV61187507; called by muse, mutect2
- OLIG3 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 82/606 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as rs1426517218, COSV62988232; called by muse, mutect2, varscan2
- OR4C5 | c.376C>A p.H126N | Missense Mutation (SNP) | VAF 20/280 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as rs1271565720; called by muse, mutect2
- REEP2 | c.166G>T p.D56Y | Missense Mutation (SNP) | VAF 103/497 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54735912; called by muse, mutect2, varscan2
- RIMS2 | c.1565C>T p.T522M (on ENST00000666250 / NM_001348490.2; = p.T330M on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/248 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1216208011, COSV51662033, COSV51669215; called by muse, mutect2
- SDK1 | c.5872G>A p.A1958T | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.636); catalogued as rs144039473; called by muse, mutect2
- SEL1L2 | c.938G>C p.G313A | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.12); catalogued as COSV53151325; called by muse, mutect2
- SPOCD1 | c.498G>C p.E166D | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV57095248; called by muse, mutect2
- STAB2 | c.205C>T p.R69* | Nonsense Mutation (SNP) | VAF 45/314 reads (14%) | catalogued as rs202064459, COSV66336983; called by muse, mutect2, varscan2
- TLR6 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 9/157 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV101126273; called by muse, mutect2
- TMEM70 | c.735G>T p.L245F | Missense Mutation (SNP) | VAF 47/165 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371278972; called by muse, mutect2, varscan2
- TOP2B | c.1969A>G p.I657V (on ENST00000264331 / NM_001330700.2; = p.I652V on NM_001068.3) | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.348); catalogued as rs1185386412; called by muse, mutect2
- TRIM2 | c.275G>A p.R92Q (on ENST00000437508; = p.R119Q on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/528 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.062); catalogued as rs753281036, COSV100108088; called by muse, mutect2
- TRPM1 | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 10/292 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as rs781379511; called by muse, mutect2
- UNKL | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 42/545 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV57018773; called by muse, mutect2
- USP46 | c.106G>T p.G36* | Nonsense Mutation (SNP) | VAF 15/164 reads (9%) | catalogued as rs868034452; called by muse, mutect2
- ZNF821 | c.310G>A p.E104K (on ENST00000425432 / NM_001376297.1; = p.E62K on NM_017530.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT tolerated, low confidence (0.51); PolyPhen possibly damaging (0.905); catalogued as rs776644514; called by muse, mutect2
- ABCA6 | c.1829A>C p.N610T | Missense Mutation (SNP) | VAF 17/327 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- ABCA9 | c.1940G>A p.G647E | Missense Mutation (SNP) | VAF 13/242 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- AFDN | c.2264A>C p.Q755P | Missense Mutation (SNP) | VAF 9/163 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2
- APBB3 | c.832G>A p.V278M (on ENST00000357560 / NM_133173.2; = p.V285M on NM_006051.3) | Missense Mutation (SNP) | VAF 26/324 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.606); called by muse, mutect2
- APOBEC3D | c.238G>C p.E80Q | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- BCL6 | c.1605G>T p.R535S | Missense Mutation (SNP) | VAF 28/563 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0.245); called by muse, mutect2
- CCDC142 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 28/504 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- CCDC81 | c.28C>A p.Q10K | Missense Mutation (SNP) | VAF 21/356 reads (6%) | SIFT tolerated (0.84); PolyPhen benign (0.08); called by muse, mutect2
- CHD1 | c.4031C>T p.S1344F | Missense Mutation (SNP) | VAF 9/156 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.063); called by muse, mutect2
- CPA3 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 8/145 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2
- DDX59 | c.1153G>C p.A385P | Missense Mutation (SNP) | VAF 16/284 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DENND4C | c.5009T>G p.I1670S (on ENST00000434457 / NM_001330640.2; = p.I1621S on NM_017925.7) | Missense Mutation (SNP) | VAF 9/166 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2
- DLL3 | c.1240C>G p.R414G | Missense Mutation (SNP) | VAF 21/195 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- EYS | c.5897A>G p.D1966G | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.883); called by muse, mutect2
- FAM241B | c.250C>T p.H84Y | Missense Mutation (SNP) | VAF 29/648 reads (4%) | SIFT tolerated (0.74); PolyPhen benign (0.271); called by muse, mutect2
- FGFR4 | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 24/322 reads (7%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2
- FOXC1 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 16/336 reads (5%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.603); called by muse, mutect2
- FZD4 | c.1415C>A p.S472Y | Missense Mutation (SNP) | VAF 48/653 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); called by muse, mutect2
- GPR63 | c.1044del p.F350Lfs*17 | Frame Shift Del (DEL) | VAF 57/346 reads (16%) | called by mutect2, pindel, varscan2
- GRID2IP | c.1859C>G p.A620G | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- IER5 | c.253G>C p.E85Q | Missense Mutation (SNP) | VAF 16/282 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.346); called by muse, mutect2
- IFT80 | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 28/520 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- KIRREL2 | c.2062A>G p.T688A | Missense Mutation (SNP) | VAF 12/281 reads (4%) | SIFT tolerated (0.42); PolyPhen benign (0.005); called by muse, mutect2
- KLHDC7B | c.209C>A p.T70N (on ENST00000395676; = p.T711N on NM_138433.5) | Missense Mutation (SNP) | VAF 48/427 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- MARCO | c.55G>C p.A19P | Missense Mutation (SNP) | VAF 14/288 reads (5%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.694); called by muse, mutect2
- MPHOSPH8 | c.321G>C p.R107S | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.516); called by muse, mutect2
- MTRR | c.1495A>G p.I499V (on ENST00000264668; = p.I472V on NM_002454.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/397 reads (4%) | SIFT tolerated (0.73); PolyPhen benign (0.005); called by muse, mutect2
- NAA25 | c.217G>T p.A73S | Missense Mutation (SNP) | VAF 30/446 reads (7%) | SIFT tolerated (0.73); PolyPhen benign (0.014); called by muse, mutect2
- NEXN | c.1885C>G p.Q629E | Missense Mutation (SNP) | VAF 23/262 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- PCDHGA8 | c.1107G>C p.L369F | Missense Mutation (SNP) | VAF 19/311 reads (6%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.042); called by muse, mutect2
- PHOSPHO2 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- PIGT | c.1178T>G p.L393R | Missense Mutation (SNP) | VAF 31/457 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- POLR1A | c.4180G>A p.E1394K | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.13); called by muse, mutect2
- PRKCH | c.142A>T p.S48C | Missense Mutation (SNP) | VAF 27/531 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); called by muse, mutect2
- PTK7 | c.2412G>C p.K804N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.229); called by muse, mutect2
- PTPRF | c.688G>T p.V230L | Missense Mutation (SNP) | VAF 26/371 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.96); called by muse, mutect2
- RASAL2 | c.2279C>T p.P760L | Missense Mutation (SNP) | VAF 12/398 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.129); called by muse, mutect2
- RECK | c.1516G>C p.E506Q | Missense Mutation (SNP) | VAF 12/340 reads (4%) | SIFT tolerated (0.47); PolyPhen benign (0.01); called by muse, mutect2
- SASH1 | c.2023G>A p.E675K | Missense Mutation (SNP) | VAF 23/453 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- SPARCL1 | c.1246G>C p.E416Q | Missense Mutation (SNP) | VAF 45/712 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.039); called by muse, mutect2
- SSRP1 | c.1783G>A p.E595K | Missense Mutation (SNP) | VAF 20/303 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.148); called by muse, mutect2
- SVIL | c.3545T>C p.M1182T (on ENST00000355867 / NM_021738.3; = p.M756T on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/364 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- TARS2 | c.214G>C p.D72H | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); called by muse, mutect2
- TFAP2B | c.872T>A p.I291N | Missense Mutation (SNP) | VAF 29/716 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TMEM169 | c.744G>A p.M248I | Missense Mutation (SNP) | VAF 48/654 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.137); called by muse, mutect2
- TRIM51 | c.357G>T p.Q119H | Missense Mutation (SNP) | VAF 21/419 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2
- TTN | c.18591G>A p.W6197* (on ENST00000591111; = p.W5270* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/152 reads (7%) | called by muse, mutect2
- YY2 | c.776G>A p.S259N | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ZFC3H1 | c.2408C>A p.S803* | Nonsense Mutation (SNP) | VAF 9/223 reads (4%) | called by muse, mutect2
- ZNF107 | c.575A>G p.E192G | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF490 | c.226C>G p.P76A | Missense Mutation (SNP) | VAF 21/388 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2
- ZNF534 | c.939T>G p.C313W (on ENST00000332323 / NM_001143939.3; = p.C300W on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF700 | c.2087G>A p.R696K | Missense Mutation (SNP) | VAF 9/163 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.009); called by muse, mutect2
- ABCC8 | c.4521C>T p.A1507= | Silent (SNP) | VAF 27/420 reads (6%) | catalogued as rs1391041542; called by muse, mutect2
- AKAP6 | c.1338C>G p.P446= | Silent (SNP) | VAF 14/164 reads (9%) | called by muse, mutect2
- ALMS1 | c.5175C>T p.A1725= | Silent (SNP) | VAF 58/392 reads (15%) | called by muse, mutect2, varscan2
- ANK1 | c.102T>C p.N34= | Silent (SNP) | VAF 141/705 reads (20%) | called by muse, mutect2, varscan2
- ANKRD13B | c.1089C>G p.T363= | Silent (SNP) | VAF 13/99 reads (13%) | called by muse, mutect2, varscan2
- BCL9L | c.2199G>C p.L733= | Silent (SNP) | VAF 36/364 reads (10%) | called by muse, mutect2
- C1orf158 | c.186A>G p.P62= | Silent (SNP) | VAF 18/306 reads (6%) | called by muse, mutect2
- CAMKK2 | c.843C>G p.L281= | Silent (SNP) | VAF 23/280 reads (8%) | called by muse, mutect2
- CARD9 | c.1239C>T p.L413= | Silent (SNP) | VAF 26/223 reads (12%) | called by muse, mutect2, varscan2
- CBWD3 | c.945G>A p.R315= | Silent (SNP) | VAF 6/13 reads (46%) | called by mutect2, varscan2
- CBWD6 | c.945G>A p.R315= | Silent (SNP) | VAF 17/111 reads (15%) | catalogued as rs1267817982; called by mutect2, varscan2
- COL11A1 | c.1290A>G p.E430= | Silent (SNP) | VAF 16/250 reads (6%) | called by muse, mutect2
- CYP3A5 | c.1344C>T p.L448= | Silent (SNP) | VAF 22/363 reads (6%) | catalogued as COSV56121465; called by muse, mutect2
- DDAH2 | c.75G>C p.S25= | Silent (SNP) | VAF 15/245 reads (6%) | catalogued as rs532560994; called by muse, mutect2
- EIPR1 | c.957C>T p.I319= | Silent (SNP) | VAF 14/161 reads (9%) | called by muse, mutect2
- ERICH3 | c.3924G>C p.A1308= | Silent (SNP) | VAF 27/260 reads (10%) | catalogued as COSV58603723; called by muse, mutect2, varscan2
- HOXB2 | c.819G>C p.S273= | Silent (SNP) | VAF 12/335 reads (4%) | catalogued as COSV100344832; called by muse, mutect2
- IGKV5-2 | c.75G>A p.T25= | Silent (SNP) | VAF 29/206 reads (14%) | catalogued as rs780945799; called by muse, mutect2, varscan2
- KRTAP13-4 | c.78C>A p.P26= | Silent (SNP) | VAF 31/283 reads (11%) | catalogued as rs755575215, COSV61880323; called by muse, mutect2, varscan2
- LY75 | c.822G>A p.K274= | Silent (SNP) | VAF 5/90 reads (6%) | catalogued as rs1370309590, COSV99717052; called by muse, mutect2
- MAGED2 | c.516C>T p.V172= | Silent (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- MGAM2 | c.4494C>T p.F1498= | Silent (SNP) | VAF 13/283 reads (5%) | called by muse, mutect2
- NBEA | c.3579C>T p.S1193= | Silent (SNP) | VAF 14/299 reads (5%) | catalogued as rs201108774; called by muse, mutect2
- OSR2 | c.507A>G p.K169= | Silent (SNP) | VAF 59/235 reads (25%) | called by muse, mutect2, varscan2
- OTOL1 | c.219G>A p.S73= | Silent (SNP) | VAF 36/578 reads (6%) | catalogued as rs780144111, COSV60007953; called by muse, mutect2
- PALD1 | c.1494C>G p.V498= | Silent (SNP) | VAF 30/406 reads (7%) | called by muse, mutect2
- RASEF | c.51C>T p.F17= | Silent (SNP) | VAF 81/678 reads (12%) | catalogued as rs554402618; called by muse, mutect2, varscan2
- SETD1A | c.4593C>T p.R1531= | Silent (SNP) | VAF 29/209 reads (14%) | catalogued as rs767366827; called by muse, mutect2, varscan2
- SLC1A5 | c.507G>A p.A169= | Silent (SNP) | VAF 36/627 reads (6%) | catalogued as rs766243500; called by muse, mutect2
- SLC26A8 | c.2103G>A p.A701= | Silent (SNP) | VAF 55/366 reads (15%) | catalogued as rs548161476; called by muse, mutect2, varscan2
- SPATA2L | c.948G>C p.L316= | Silent (SNP) | VAF 28/288 reads (10%) | catalogued as rs754513039, COSV57048691; called by muse, mutect2
- SPATA31D1 | c.528C>A p.P176= | Silent (SNP) | VAF 74/495 reads (15%) | catalogued as rs762302026, COSV61194326, COSV61196326; called by muse, mutect2, varscan2
- SPZ1 | c.831C>T p.D277= | Silent (SNP) | VAF 8/126 reads (6%) | called by muse, mutect2
- TANGO6 | c.1251C>G p.L417= | Silent (SNP) | VAF 19/159 reads (12%) | called by muse, mutect2, varscan2
- TBL2 | c.198G>A p.R66= | Silent (SNP) | VAF 20/446 reads (4%) | called by muse, mutect2
- TGFBR2 | c.1374A>G p.T458= | Silent (SNP) | VAF 33/418 reads (8%) | called by muse, mutect2
- TIMM29 | c.34C>A p.R12= | Silent (SNP) | VAF 8/228 reads (4%) | called by muse, mutect2
- XKR8 | c.483C>T p.Y161= | Silent (SNP) | VAF 17/104 reads (16%) | catalogued as rs754797378; called by muse, varscan2
- ZNF345 | c.96A>G p.E32= | Silent (SNP) | VAF 9/162 reads (6%) | called by muse, mutect2
- AMPH | c.1183-1185T>A | Intron (SNP) | VAF 20/316 reads (6%) | called by muse, mutect2
- AP000769.5 | chr11:65498989 T>C | 5'Flank (SNP) | VAF 22/232 reads (9%) | catalogued as rs754397792; called by muse, mutect2
- CBFA2T2 | c.-270C>G | 5'UTR (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- CLDN14 | c.*47C>T | 3'UTR (SNP) | VAF 22/264 reads (8%) | catalogued as rs758566130; called by muse, mutect2
- DDX41 | c.*369G>C | 3'UTR (SNP) | VAF 17/409 reads (4%) | called by muse, mutect2
- DYNC1I2 | c.245-26G>A | Intron (SNP) | VAF 28/343 reads (8%) | catalogued as rs777344607, COSV55526985, COSV99783685; called by muse, mutect2
- EPDR1 | c.-31C>A | 5'UTR (SNP) | VAF 36/390 reads (9%) | catalogued as COSV99554179; called by muse, mutect2
- FAM71E1 | c.-108G>A | 5'UTR (SNP) | VAF 25/322 reads (8%) | catalogued as rs1487512865; called by muse, mutect2
- GTF2IRD2P1 | n.1960G>C | RNA (SNP) | VAF 68/1123 reads (6%) | called by muse, mutect2
- HSPA7 | n.181G>A | RNA (SNP) | VAF 31/730 reads (4%) | called by muse, mutect2
- IQCG | c.-59-5665G>A | Intron (SNP) | VAF 70/302 reads (23%) | catalogued as rs369611749; called by muse, mutect2, varscan2
- KDR | c.2615-45G>A | Intron (SNP) | VAF 11/180 reads (6%) | called by muse, mutect2
- MIGA2 | c.1459-122C>G | Intron (SNP) | VAF 16/177 reads (9%) | catalogued as rs773569246; called by muse, mutect2
- PPM1B | c.1134+308G>T | Intron (SNP) | VAF 5/86 reads (6%) | called by muse, mutect2
- SEC63 | c.1501-34A>G | Intron (SNP) | VAF 43/258 reads (17%) | catalogued as rs754164589; called by muse, mutect2, varscan2
- TNS1 | c.2632+5404G>C | Intron (SNP) | VAF 21/257 reads (8%) | called by muse, mutect2
- WDR55 | c.-9C>T | 5'UTR (SNP) | VAF 16/306 reads (5%) | catalogued as rs1212361331; called by muse, mutect2
